Somatic mutation profile of tumor specimen TCGA-EJ-5496-01A (aliquot TCGA-EJ-5496-01A-01D-1576-08) from TCGA case TCGA-EJ-5496, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.0 years (21,897 days).
Specimen TCGA-EJ-5496-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d550bb6f-85d3-45df-b83a-eb4ac04c6acb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5496-10A (Blood Derived Normal), aliquot TCGA-EJ-5496-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b58e3f59-4367-4d63-8836-70d6da98a6bb

The open-access MAF lists 35 somatic variants for this specimen: 30 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 26, Silent 5, Nonsense Mutation 2, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTC1 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV51759315; called by muse, mutect2
- ADGRL3 | c.2699G>T p.W900L (on ENST00000506720 / NM_001322402.2; = p.W832L on NM_015236.6) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV72230670; called by muse, mutect2, varscan2
- ASB5 | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV56670888, COSV56673726; called by muse, mutect2
- ATF7IP | c.3357G>C p.Q1119H | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53771317; called by muse, mutect2, varscan2
- B3GALNT1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.446); catalogued as rs143966469; called by muse, mutect2, varscan2
- CCDC150 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs373323546; called by muse, mutect2
- CSMD1 | c.8831G>A p.R2944H (on ENST00000520002; = p.R2943H on NM_033225.6) | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as rs374773802; called by muse, mutect2, varscan2
- DMBX1 | c.745C>T p.L249F | Missense Mutation (SNP) | VAF 67/409 reads (16%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.101); catalogued as COSV63602070; called by muse, mutect2, varscan2
- FAM155A | c.964T>C p.F322L | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs765508512, COSV101028124, COSV65563466; called by muse, mutect2, varscan2
- H1-1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV55119517; called by muse, mutect2
- HKDC1 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.666); catalogued as rs952016916, COSV63577325; called by muse, mutect2, varscan2
- IRX1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57359651; called by muse, mutect2, varscan2
- KCNT2 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 57/240 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs778987960, COSV54081501, COSV54090551; called by muse, mutect2, varscan2
- LRRC4B | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV65349610, COSV65350566; called by muse, mutect2, varscan2
- MUC16 | c.34531C>T p.H11511Y | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV67468806; called by muse, mutect2, varscan2
- MYCT1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs375330501; called by muse, mutect2, varscan2
- NBAS | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 58/346 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs764102523, COSV55722643; called by muse, mutect2, varscan2
- NSD1 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.34); catalogued as rs587784074, COSV61776760; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OSBPL10 | c.1977G>A p.W659* | Nonsense Mutation (SNP) | VAF 75/340 reads (22%) | catalogued as COSV67339628; called by muse, mutect2, varscan2
- PAX5 | c.910G>T p.G304C | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63907754, COSV63909300; called by muse, varscan2
- POT1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 23/126 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV62928594, COSV62929308; called by muse, mutect2, varscan2
- RAPGEF6 | c.4354C>T p.Q1452* | Nonsense Mutation (SNP) | VAF 72/357 reads (20%) | catalogued as rs764526893, COSV57247050; called by muse, mutect2, varscan2
- RP1 | c.2039C>T p.A680V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1563330406, COSV55117747; called by muse, mutect2
- SALL4 | c.2935G>A p.G979S | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779372301, COSV53852523; called by muse, mutect2, varscan2
- SULT1E1 | c.271+2T>A p.X91_splice | Splice Site (SNP) | VAF 10/89 reads (11%) | catalogued as COSV56947248; called by muse, mutect2, varscan2
- TM7SF2 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.223); catalogued as COSV54207554; called by muse, mutect2, varscan2
- TRIM36 | c.1562G>A p.C521Y | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.938); catalogued as COSV56690406; called by muse, mutect2, varscan2
- TUBA3C | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV68028257; called by muse, mutect2, varscan2
- ZFAND5 | c.617T>G p.V206G | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52988715; called by muse, mutect2, varscan2
- ZNRF2 | c.715C>A p.H239N | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59911095; called by muse, mutect2, varscan2
- ARID1A | c.6372A>G p.K2124= | Silent (SNP) | VAF 45/202 reads (22%) | catalogued as COSV61378343; called by muse, mutect2, varscan2
- ASXL1 | c.3213G>A p.A1071= | Silent (SNP) | VAF 59/213 reads (28%) | catalogued as rs756414158, COSV60108404; called by muse, mutect2, varscan2
- KIAA1109 | c.8076G>A p.V2692= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as COSV52674843; called by muse, mutect2
- MAN1A1 | c.1377C>T p.I459= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as rs757838527, COSV63787625; called by muse, mutect2, varscan2
- UBTF | c.369C>T p.F123= | Silent (SNP) | VAF 52/202 reads (26%) | catalogued as COSV57186253; called by muse, mutect2, varscan2
